Somatic mutation profile of tumor specimen MBCProject_1160_T1_WES (aliquot MBCProject_1160_T1_WES_1) from CMI case MBCProject_1160, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 29.8 years (10,901 days).
Specimen MBCProject_1160_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d5754e5-e748-4f4e-a766-8a435dbd0216.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1160_SALIVA (Saliva), aliquot MBCProject_1160_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff53d25f-6b32-4430-85bb-460564f3f0fc

The open-access MAF lists 69 somatic variants for this specimen: 46 protein-altering or splice-affecting, 12 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 12, Intron 6, Nonsense Mutation 3, 5'UTR 2, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1, RNA 1, Translation Start Site 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 94/183 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CD93 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.917); catalogued as rs370755930; called by muse, varscan2
- DNM1L | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 82/260 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.509); catalogued as COSV56776060; called by muse, mutect2, varscan2
- EPO | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.415); catalogued as rs200241729; called by muse, mutect2, varscan2
- FRMD1 | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as rs774332500; called by muse, mutect2, varscan2
- MAGEB18 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57464301; called by mutect2, varscan2
- MAST4 | c.3133C>T p.R1045* (on ENST00000403625 / NM_001164664.2; = p.R856* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 94/194 reads (48%) | catalogued as rs367575904, COSV55146202; called by muse, mutect2, varscan2
- NACC2 | c.1733G>A p.R578K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.035); catalogued as rs775806391; called by muse, mutect2, varscan2
- PPP1R16B | c.1005G>T p.R335S | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55385769; called by muse, mutect2, varscan2
- SPRED2 | c.474G>C p.K158N | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.133); catalogued as COSV100710013; called by muse, mutect2, varscan2
- TTN | c.36018G>T p.K12006N (on ENST00000591111; = p.K4582N on NM_003319.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | PolyPhen possibly damaging (0.724); catalogued as COSV60443116; called by muse, mutect2
- ADAMTSL1 | c.2855C>T p.A952V | Missense Mutation (SNP) | VAF 117/297 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- AP1B1 | c.2110G>C p.D704H | Missense Mutation (SNP) | VAF 211/905 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- B3GNT9 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CES4A | c.1221G>C p.E407D | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHADL | c.235G>C p.A79P | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CPT1B | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 252/390 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, varscan2
- CPT1B | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 390/554 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, varscan2
- CUL3 | c.1727_1744del p.G576_Q581del | In Frame Del (DEL) | VAF 73/277 reads (26%) | called by mutect2, pindel, varscan2
- DENND6B | c.959C>A p.T320N | Missense Mutation (SNP) | VAF 30/353 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAAF5 | c.1340C>G p.T447R | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- DNAH5 | c.12106T>G p.W4036G | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- DRAP1 | c.133T>C p.F45L | Missense Mutation (SNP) | VAF 100/324 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOG | c.375T>G p.S125R | Missense Mutation (SNP) | VAF 105/299 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- GDI1 | c.256C>A p.Q86K | Missense Mutation (SNP) | VAF 70/367 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GFPT1 | c.857A>T p.E286V (on ENST00000357308 / NM_001244710.2; = p.E268V on NM_002056.4) | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- GPANK1 | c.1045A>T p.R349W | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- KCNV2 | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF1A | c.3904C>T p.R1302C (on ENST00000320389 / NM_001379639.1; = p.R1294C on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LSM10 | c.143C>G p.A48G | Missense Mutation (SNP) | VAF 228/498 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- LTBP3 | c.1040G>T p.R347M | Missense Mutation (SNP) | VAF 129/394 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- LZTR1 | c.937T>C p.C313R | Missense Mutation (SNP) | VAF 45/475 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.212); called by muse, mutect2
- MED12L | c.4640T>C p.L1547P | Missense Mutation (SNP) | VAF 58/280 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- MROH7 | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTPAP | c.331-46_331-1del p.X111_splice | Splice Site (DEL) | VAF 42/342 reads (12%) | called by mutect2, pindel
- NXF1 | c.313A>T p.R105* | Nonsense Mutation (SNP) | VAF 115/383 reads (30%) | called by muse, mutect2, varscan2
- NXF1 | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 116/390 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- RP1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 73/234 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SENP2 | c.190T>C p.Y64H | Missense Mutation (SNP) | VAF 70/256 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TCTN1 | c.669_675del p.S224* | Frame Shift Del (DEL) | VAF 67/161 reads (42%) | called by pindel, varscan2
- TP63 | c.1028_1029dup p.I344Gfs*45 | Frame Shift Ins (INS) | VAF 129/426 reads (30%) | called by pindel, varscan2
- UNC13D | c.2404C>A p.L802I | Missense Mutation (SNP) | VAF 163/320 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- USP19 | c.3484A>T p.I1162F | Missense Mutation (SNP) | VAF 62/230 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- WIZ | c.3196G>C p.A1066P (on ENST00000673675 / NM_001371589.1; = p.A243P on NM_001330395.4) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZBTB14 | c.947C>A p.T316K | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZCCHC14 | c.377C>A p.S126* (on ENST00000268616; = p.S263* on NM_015144.3) | Nonsense Mutation (SNP) | VAF 74/239 reads (31%) | called by muse, mutect2, varscan2
- CDKN2D | c.96G>T p.L32= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as rs779724613; called by muse, mutect2, varscan2
- FES | c.1179C>T p.P393= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs201149672; called by muse, mutect2, varscan2
- IGFN1 | c.522A>C p.A174= | Silent (SNP) | VAF 56/130 reads (43%) | catalogued as rs1294036190; called by muse, mutect2, varscan2
- KNG1 | c.36G>A p.R12= | Silent (SNP) | VAF 71/241 reads (29%) | called by muse, mutect2, varscan2
- LCT | c.726G>A p.T242= | Silent (SNP) | VAF 9/182 reads (5%) | catalogued as rs1249832435, COSV51557861; called by muse, mutect2
- LTN1 | c.1407C>T p.A469= | Silent (SNP) | VAF 101/431 reads (23%) | called by muse, mutect2, varscan2
- MARF1 | c.3171T>G p.V1057= | Silent (SNP) | VAF 49/139 reads (35%) | called by muse, mutect2, varscan2
- PGBD4 | c.1296C>T p.D432= | Silent (SNP) | VAF 92/233 reads (39%) | called by muse, mutect2, varscan2
- PI4KA | c.3255C>T p.N1085= | Silent (SNP) | VAF 98/122 reads (80%) | called by muse, mutect2, varscan2
- SEC24D | c.468A>G p.P156= | Silent (SNP) | VAF 77/318 reads (24%) | called by muse, mutect2, varscan2
- SIDT2 | c.603C>A p.S201= | Silent (SNP) | VAF 13/206 reads (6%) | called by muse, mutect2
- UBL4A | c.235C>T p.L79= | Silent (SNP) | VAF 36/195 reads (18%) | called by muse, mutect2, varscan2
- ATG2B | c.2737-23del | Intron (DEL) | VAF 12/83 reads (14%) | catalogued as rs750652328; called by mutect2, varscan2
- CDKN2A | chr9:21967318 G>A | 3'Flank (SNP) | VAF 126/411 reads (31%) | catalogued as rs768959694; called by muse, mutect2, varscan2
- CFAP74 | c.2176+84G>A | Intron (SNP) | VAF 16/30 reads (53%) | catalogued as rs747264122; called by muse, mutect2, varscan2
- DCHS2 | n.4015T>C | RNA (SNP) | VAF 121/315 reads (38%) | called by muse, mutect2, varscan2
- HNF1A | c.-93T>C | 5'UTR (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- KATNBL1 | c.883-623C>G | Intron (SNP) | VAF 75/225 reads (33%) | called by muse, mutect2, varscan2
- LAMA1 | c.-43C>T | 5'UTR (SNP) | VAF 68/193 reads (35%) | catalogued as rs758867374; called by muse, mutect2, varscan2
- PAPOLA | c.2005-9del | Intron (DEL) | VAF 29/190 reads (15%) | catalogued as rs750373066; called by mutect2, varscan2
- PPP1R13L | c.1354+160G>A | Intron (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- RAB17 | chr2:237591222 GC>ATTCTTCAGGAGACTCTAGT | 5'Flank (INS) | VAF 47/219 reads (21%) | catalogued as rs796117391; called by pindel, varscan2*
- ZFYVE9 | c.2278+13del | Intron (DEL) | VAF 49/199 reads (25%) | called by mutect2, pindel, varscan2
